Somatic mutation profile of tumor specimen BLGSP-71-08-00057-01A (aliquot BLGSP-71-08-00057-01A-01D-A671-33) from CGCI case BLGSP-71-08-00057, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.4 years (2,325 days).
Specimen BLGSP-71-08-00057-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Spleen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 909924b1-2c7d-409a-91bc-154fa256794e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00057-10A (Blood Derived Normal), aliquot BLGSP-71-08-00057-10A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/495b90cc-e322-41d7-8d2b-ebe100cd01fe

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Del 2, 5'UTR 2, 5'Flank 2, Splice Site 1, Nonstop Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.706T>A p.Y236N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782289, CM1411658, COSV52672888, COSV52675514, COSV52783032; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DDX3X | c.1582A>T p.I528F (on ENST00000399959; = p.I529F on NM_001356.5) | Missense Mutation (SNP) | VAF 253/257 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863027; called by muse, mutect2, varscan2
- GNAI2 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104382018; called by muse, mutect2, varscan2
- H1-4 | c.316A>C p.K106Q | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56800702; called by muse, mutect2, varscan2
- TNFRSF14 | c.69+2T>G p.X23_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV63186558, COSV63187296; called by muse, mutect2, varscan2
- AC072022.2 | c.117G>C p.*39Yext*70 | Nonstop Mutation (SNP) | VAF 108/226 reads (48%) | called by muse, varscan2
- ARID1A | c.1330_1333del p.G444Sfs*174 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel
- H2BC12 | c.110G>C p.S37T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KMT2D | c.13110del p.F4370Lfs*14 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- H2BC12 | c.111C>T p.S37= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs751499348, COSV63617388; called by muse, mutect2, varscan2
- BCL6 | c.-73T>G | 5'UTR (SNP) | VAF 106/226 reads (47%) | called by muse, varscan2
- BCL6 | chr3:187745473 A>C | 5'Flank (SNP) | VAF 116/246 reads (47%) | called by muse, varscan2
- MYC | c.-412A>G | 5'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2
- TSPOAP1 | chr17:58332119 C>G | 5'Flank (SNP) | VAF 109/240 reads (45%) | catalogued as rs188347091; called by muse, mutect2, varscan2
